Somatic mutation profile of tumor specimen TCGA-BP-5190-01A (aliquot TCGA-BP-5190-01A-01D-1429-08) from TCGA case TCGA-BP-5190, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.0 years (22,285 days).
Specimen TCGA-BP-5190-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9be72017-1a7e-48b3-a2c0-8a0cc3da3c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5190-11A (Solid Tissue Normal), aliquot TCGA-BP-5190-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/221eed5d-8a80-48fc-93bb-ed6fea2f8c1b

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 37/151 reads (25%) | catalogued as COSV60041301; called by muse, mutect2, varscan2
- AGPAT5 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV53448501; called by muse, mutect2, varscan2
- BCL6 | c.1345A>G p.I449V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs775834769, COSV51654414; called by muse, mutect2, varscan2
- CCHCR1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.442); catalogued as rs576214578, COSV66161201, COSV66161514; called by muse, mutect2
- CD6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV57841005; called by muse, mutect2, varscan2
- CNTN3 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55179645; called by muse, mutect2, varscan2
- CPS1 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs746628905, COSV51818734; called by muse, mutect2, varscan2
- CTNNA2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63587511; called by muse, mutect2, varscan2
- DIP2C | c.1679T>C p.M560T | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV55170891; called by muse, mutect2, varscan2
- FUT11 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV59543764; called by muse, mutect2, varscan2
- GAS6 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59853877; called by muse, mutect2, varscan2
- IGFLR1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV53075913; called by muse, mutect2, varscan2
- IPO9 | c.3077G>T p.G1026V | Missense Mutation (SNP) | VAF 149/530 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64234841; called by muse, mutect2, varscan2
- KDM5C | c.2198A>C p.H733P | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64767404; called by muse, mutect2, varscan2
- KMT2B | c.4747C>T p.L1583F | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as COSV55865947; called by muse, mutect2, varscan2
- KSR2 | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV56679226; called by muse, mutect2, varscan2
- LAMP3 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs1010431829, COSV55616252; called by muse, mutect2, varscan2
- LSM11 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as COSV51453405; called by muse, mutect2
- MAGEE2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1415059199, COSV100973257, COSV64898197; called by muse, mutect2, varscan2
- MINK1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs774288331, COSV61791839; called by muse, varscan2
- MRPS21 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs781890154, COSV58414404; called by muse, mutect2, varscan2
- MUC16 | c.39161C>T p.S13054F | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV67481263; called by muse, mutect2, varscan2
- MUC16 | c.39160T>A p.S13054T | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV67481265; called by muse, mutect2, varscan2
- NCKAP5 | c.3373G>T p.A1125S | Missense Mutation (SNP) | VAF 117/413 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs371372513, COSV58450719; called by muse, mutect2, varscan2
- PBRM1 | c.1797del p.Y600Ifs*42 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as COSV56265934; called by mutect2, pindel, varscan2
- PEPD | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54893977; called by muse, mutect2, varscan2
- POSTN | c.1563G>T p.L521F | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV65713939, COSV65714714; called by muse, mutect2, varscan2
- RPL31 | c.346+1G>C p.X116_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as COSV51822614; called by muse, mutect2, varscan2
- SCD5 | c.53A>C p.E18A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV51103845; called by muse, mutect2, varscan2
- VPS41 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59651462; called by muse, mutect2, varscan2
- EMILIN1 | c.2576_2581del p.X859_splice | Splice Site (DEL) | VAF 26/136 reads (19%) | called by mutect2, pindel, varscan2
- NKG7 | c.443_453del p.A148Gfs*12 | Frame Shift Del (DEL) | VAF 70/432 reads (16%) | called by mutect2, pindel, varscan2
- ARID2 | c.3795C>A p.V1265= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV57610710; called by muse, mutect2, varscan2
- ELAC2 | c.327C>T p.F109= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as COSV62033614; called by muse, mutect2, varscan2
- HCFC1 | c.36G>T p.A12= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV60075504; called by muse, varscan2
- SCRN3 | c.945G>A p.V315= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as COSV55809120; called by muse, mutect2, varscan2
- TRPC3 | c.651C>T p.D217= (on ENST00000379645 / NM_001366479.2; = p.D144= on NM_003305.2) | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs769632483, COSV53378671, COSV53383696; called by muse, mutect2, varscan2
- VPS13D | c.12816T>A p.I4272= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as COSV50662069; called by muse, mutect2, varscan2
- EEF1D | c.-7-3034C>T | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs752981152, COSV57821692; called by mutect2, varscan2
